Somatic mutation profile of tumor specimen C3N-02063-01 (aliquot CPT0134660009) from CPTAC case C3N-02063, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 49.7 years (18,159 days).
Specimen C3N-02063-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 773230b8-9b78-4542-b10d-1935af1bdf6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02063-71 (Blood Derived Normal), aliquot CPT0134780002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7212d2ce-1443-43e9-8d24-1c22f7a402b9

The open-access MAF lists 45 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Frame Shift Del 3, Intron 3, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.485G>A p.C162Y | Missense Mutation (SNP) | VAF 45/522 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs397516444, CM951291, CM951292, COSV56546524, COSV56553028, COSV56557871; ClinVar: pathogenic; called by muse, mutect2
- AQP1 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 48/408 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs777773161; called by muse, mutect2, varscan2
- FTH1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 46/658 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs755508306, COSV56445029; called by muse, mutect2
- OR6C75 | c.284G>A p.C95Y | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as rs774226403; called by muse, mutect2
- PCDHAC2 | c.1449G>T p.L483F | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs782676713; called by muse, mutect2
- PCNT | c.4552C>T p.R1518C | Missense Mutation (SNP) | VAF 88/862 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs763712724; ClinVar: uncertain significance; called by muse, mutect2
- SYK | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773478505, COSV65328614; called by muse, mutect2
- ABL2 | c.2519G>C p.S840T (on ENST00000502732 / NM_007314.4; = p.S825T on NM_005158.5) | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- C20orf194 | c.3072G>A p.M1024I | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.055); called by muse, mutect2
- CD37 | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.067); called by muse, mutect2
- CDC20 | c.70C>G p.P24A | Missense Mutation (SNP) | VAF 44/386 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- CFP | c.982A>T p.I328F | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CHSY1 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 55/432 reads (13%) | called by muse, mutect2, varscan2
- CLDN9 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 32/532 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2
- CLEC4E | c.467C>A p.T156K | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- CXCR4 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- DCAF15 | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DDX10 | c.1084del p.V362Sfs*23 | Frame Shift Del (DEL) | VAF 19/174 reads (11%) | called by mutect2, varscan2
- FLG2 | c.5917G>A p.G1973R | Missense Mutation (SNP) | VAF 49/485 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GABBR2 | c.524C>G p.T175S | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- GET3 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 30/345 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HIVEP1 | c.6139A>T p.N2047Y | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- LRP8 | c.158A>T p.Q53L | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2
- MED1 | c.2185_2188del p.T729Lfs*50 | Frame Shift Del (DEL) | VAF 22/212 reads (10%) | called by mutect2, pindel
- PAPOLG | c.1921G>C p.V641L | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PHOSPHO2 | c.576T>A p.N192K | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPIN1 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.546); called by muse, mutect2
- SWT1 | c.1445A>T p.E482V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TADA2A | c.424A>T p.T142S | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2
- TMEM259 | c.806G>A p.S269N | Missense Mutation (SNP) | VAF 35/368 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- TRO | c.467del p.P156Qfs*11 | Frame Shift Del (DEL) | VAF 47/247 reads (19%) | called by mutect2, pindel, varscan2
- UBN1 | c.2293T>C p.C765R | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CUEDC2 | c.60G>A p.P20= | Silent (SNP) | VAF 30/305 reads (10%) | catalogued as rs200755540; called by muse, mutect2
- CUX2 | c.2514G>A p.A838= | Silent (SNP) | VAF 25/204 reads (12%) | catalogued as rs573123343; called by muse, varscan2
- ENDOV | c.738C>T p.H246= | Silent (SNP) | VAF 13/274 reads (5%) | called by muse, mutect2
- FBXO10 | c.1074G>T p.L358= | Silent (SNP) | VAF 22/195 reads (11%) | catalogued as rs373735502; called by muse, mutect2, varscan2
- IL20RB | c.435C>T p.I145= | Silent (SNP) | VAF 27/274 reads (10%) | called by muse, mutect2, varscan2
- NODAL | c.51C>G p.L17= | Silent (SNP) | VAF 37/308 reads (12%) | catalogued as rs369058589; called by muse, mutect2, varscan2
- PIK3CG | c.1764A>G p.A588= | Silent (SNP) | VAF 26/253 reads (10%) | called by muse, mutect2, varscan2
- PML | c.1173C>A p.T391= | Silent (SNP) | VAF 34/376 reads (9%) | called by muse, mutect2
- ZBTB45 | c.1518G>T p.A506= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs760003666; called by muse, mutect2
- ABR | c.1962-35G>A | Intron (SNP) | VAF 7/55 reads (13%) | catalogued as rs753857811; called by muse, mutect2
- CDK10 | c.87+724G>A | Intron (SNP) | VAF 22/216 reads (10%) | called by muse, mutect2, varscan2
- IPO4 | c.2472+19A>T | Intron (SNP) | VAF 31/244 reads (13%) | called by muse, mutect2, varscan2
- TERT | c.-29G>A | 5'UTR (SNP) | VAF 7/63 reads (11%) | catalogued as COSV57230902; called by muse, mutect2, varscan2
